Somatic mutation profile of tumor specimen TARGET-10-PARMWH-09A (aliquot TARGET-10-PARMWH-09A-01D) from TARGET case TARGET-10-PARMWH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 20.6 years (7,513 days).
Specimen TARGET-10-PARMWH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b9c6d4e-e55a-41fd-b9be-163587c2754e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMWH-14A (Bone Marrow Normal), aliquot TARGET-10-PARMWH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ae8a632-736d-47b9-85dd-7f951cb0862a

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Splice Site 1, Intron 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.2810T>C p.V937A | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV52390289; called by muse, mutect2, varscan2
- ARHGEF12 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs577733342, COSV63105045; called by muse, mutect2, varscan2
- DOCK11 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs565013054, COSV52246645; called by muse, mutect2, varscan2
- FCGRT | c.398T>C p.F133S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV55530811; called by muse, mutect2, varscan2
- KDM6A | c.171_172insAGATACCG p.G58Rfs*6 | Frame Shift Ins (INS) | VAF 31/68 reads (46%) | catalogued as COSV65044714; called by mutect2, pindel, varscan2
- NOTCH1 | c.5087C>A p.A1696D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53034439; called by muse, mutect2
- NOTCH1 | c.4757G>C p.R1586P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); catalogued as COSV53047710; called by muse, varscan2
- NTM | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); catalogued as rs1289145335, COSV100868674, COSV66178113; called by muse, mutect2, varscan2
- RBM41 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52562722; called by muse, mutect2, varscan2
- SBSN | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as rs182436431; called by muse, mutect2, varscan2
- TCTN1 | c.341+1G>A p.X114_splice | Splice Site (SNP) | VAF 39/94 reads (41%) | catalogued as rs200241085; called by muse, mutect2, varscan2
- TNFRSF4 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as rs757655414, COSV55421211; called by muse, mutect2, varscan2
- LDLR | c.18del p.W6* | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.2958C>T p.G986= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1434678993, COSV65888269; called by muse, mutect2, varscan2
- FBN2 | c.5859A>T p.G1953= | Silent (SNP) | VAF 93/193 reads (48%) | called by muse, mutect2
- MAPK8IP1 | c.891C>T p.S297= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs983091897, COSV99571815; called by muse, mutect2, varscan2
- PRRC2B | c.3552C>T p.C1184= | Silent (SNP) | VAF 57/105 reads (54%) | catalogued as rs750192495; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1057-59C>T | Intron (SNP) | VAF 27/49 reads (55%) | catalogued as rs1488666969, COSV64182283; called by muse, mutect2, varscan2
